Somatic mutation profile of tumor specimen MMRF_1179_1_BM_CD138pos (aliquot MMRF_1179_1_BM_CD138pos_T2_KHS5U_L13431) from MMRF case MMRF_1179, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 80.4 years (29,365 days).
Specimen MMRF_1179_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39bc489c-fa79-4d60-90ef-ed398f1ae8cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1179_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1179_1_PB_Whole_C1_KHS5U_L13430; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64fac6b0-71a0-4956-88cf-70e55847a3ab

The open-access MAF lists 107 somatic variants for this specimen: 40 protein-altering or splice-affecting, 7 silent, 60 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 32, Missense Mutation 31, Intron 22, Silent 7, Frame Shift Del 3, RNA 3, Splice Site 2, Nonsense Mutation 2, Translation Start Site 2, 5'UTR 2, IGR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTNAP3B | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 92/331 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1298872013; called by muse, mutect2, varscan2
- CYP2A13 | c.47C>G p.T16S | Missense Mutation (SNP) | VAF 97/202 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57837639; called by muse, mutect2, varscan2
- ENTPD8 | c.178C>A p.Q60K | Missense Mutation (SNP) | VAF 117/274 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV58160849; called by muse, mutect2, varscan2
- GMIP | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs759085807; called by muse, mutect2, varscan2
- IGHV2-70 | c.56C>G p.S19C | Missense Mutation (SNP) | VAF 52/56 reads (93%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs576362735; called by muse, varscan2
- IGHV4-39 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 32/71 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.525); catalogued as rs770953468; called by muse, varscan2
- IGLV3-1 | c.277A>T p.I93F | Missense Mutation (SNP) | VAF 116/120 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs548457166; called by muse, varscan2
- IRF8 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV51896682; called by muse, mutect2, varscan2
- MSH4 | c.2583del p.K862Rfs*30 | Frame Shift Del (DEL) | VAF 42/104 reads (40%) | catalogued as COSV54196091; called by mutect2, pindel, varscan2
- AASDH | c.2860G>A p.G954S | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCG2 | c.1865C>A p.S622* | Nonsense Mutation (SNP) | VAF 157/891 reads (18%) | called by muse, mutect2, varscan2
- CCDC88A | c.127G>C p.V43L | Missense Mutation (SNP) | VAF 186/444 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- DDX60 | c.2024G>A p.R675K | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- DRD5 | c.584A>C p.N195T | Missense Mutation (SNP) | VAF 96/173 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FHDC1 | c.3125C>T p.S1042F | Missense Mutation (SNP) | VAF 82/430 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GCM1 | c.199C>T p.H67Y | Missense Mutation (SNP) | VAF 107/263 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HDAC4 | c.3082_3104del p.W1028Lfs*40 | Frame Shift Del (DEL) | VAF 54/154 reads (35%) | called by mutect2, pindel, varscan2
- IGHV2-70D | c.53T>A p.L18* | Nonsense Mutation (SNP) | VAF 65/70 reads (93%) | called by muse, varscan2
- KIF3C | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- L3MBTL3 | c.1188G>A p.M396I | Missense Mutation (SNP) | VAF 137/279 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LIMD2 | c.199T>A p.C67S | Missense Mutation (SNP) | VAF 92/176 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- LRPPRC | c.2365T>G p.F789V | Missense Mutation (SNP) | VAF 97/219 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- MYO5A | c.1784A>C p.D595A | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NCKAP5L | c.168G>C p.E56D | Missense Mutation (SNP) | VAF 116/121 reads (96%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- NLRP6 | c.53C>G p.A18G | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PATL1 | c.1486A>G p.M496V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- PITX3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 86/159 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- PREX1 | c.2681A>G p.D894G | Missense Mutation (SNP) | VAF 73/153 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RPL24 | c.82-2A>G p.X28_splice | Splice Site (SNP) | VAF 67/134 reads (50%) | called by muse, mutect2, varscan2
- SCLT1 | c.1561A>G p.K521E | Missense Mutation (SNP) | VAF 124/267 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNAP91 | c.*10+2T>G | Splice Site (SNP) | VAF 141/292 reads (48%) | called by muse, mutect2, varscan2
- TACC2 | c.7157A>G p.K2386R (on ENST00000334433; = p.K464R on NM_006997.4) | Missense Mutation (SNP) | VAF 186/351 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TASOR2 | c.2939C>T p.T980I | Missense Mutation (SNP) | VAF 80/186 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TBC1D22B | c.734A>G p.Y245C | Missense Mutation (SNP) | VAF 119/236 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TOPAZ1 | c.2289T>A p.N763K | Missense Mutation (SNP) | VAF 42/237 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TRAFD1 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 193/204 reads (95%) | SIFT tolerated (0.14); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TTN | c.94271_94281del p.E31424Vfs*2 (on ENST00000591111; = p.E24000Vfs*2 on NM_003319.4) | Frame Shift Del (DEL) | VAF 156/450 reads (35%) | called by pindel, varscan2
- TUSC3 | c.367T>A p.C123S | Missense Mutation (SNP) | VAF 90/198 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFP62 | c.1877T>G p.F626C (on ENST00000502412 / NM_001377944.1; = p.F593C on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 94/231 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZSCAN16 | c.655A>G p.I219V | Missense Mutation (SNP) | VAF 190/384 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAB39 | c.942G>A p.T314= | Silent (SNP) | VAF 128/276 reads (46%) | catalogued as rs146490647; called by muse, mutect2, varscan2
- CD177 | c.162G>T p.G54= | Silent (SNP) | VAF 33/68 reads (49%) | called by muse, mutect2, varscan2
- CH25H | c.606C>A p.T202= | Silent (SNP) | VAF 120/239 reads (50%) | called by muse, mutect2, varscan2
- DOCK6 | c.4437G>A p.T1479= | Silent (SNP) | VAF 46/138 reads (33%) | catalogued as rs1433085969; called by muse, mutect2, varscan2
- LIMD2 | c.234C>T p.S78= | Silent (SNP) | VAF 56/132 reads (42%) | catalogued as rs1380154462; called by muse, varscan2
- PI4KB | c.2115G>A p.T705= (on ENST00000368873 / NM_001369623.1; = p.T717= on NM_002651.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 50/123 reads (41%) | catalogued as rs1310794851; called by muse, mutect2, varscan2
- TNKS1BP1 | c.528T>G p.L176= | Silent (SNP) | VAF 76/174 reads (44%) | called by muse, mutect2, varscan2
- AC011487.1 | n.133G>C | RNA (SNP) | VAF 22/40 reads (55%) | called by muse, mutect2, varscan2
- ADGRG2 | c.263-44del | Intron (DEL) | VAF 23/33 reads (70%) | called by mutect2, pindel, varscan2
- AEBP2 | c.1508+37G>A | Intron (SNP) | VAF 185/211 reads (88%) | catalogued as rs1054971858; called by muse, mutect2, varscan2
- ANAPC4 | c.1623+114C>T | Intron (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- ARHGEF12 | c.*803T>C | 3'UTR (SNP) | VAF 60/164 reads (37%) | called by muse, mutect2, varscan2
- ATP13A5 | c.*27C>G | 3'UTR (SNP) | VAF 47/93 reads (51%) | called by muse, mutect2, varscan2
- BBS2 | c.1081-142G>C | Intron (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2, varscan2
- CCSER1 | c.*451G>A | 3'UTR (SNP) | VAF 47/96 reads (49%) | called by muse, mutect2, varscan2
- CEP104 | c.*231T>G | 3'UTR (SNP) | VAF 45/96 reads (47%) | called by muse, mutect2, varscan2
- CNTNAP3P2 | n.801G>A | RNA (SNP) | VAF 29/211 reads (14%) | catalogued as rs1414224469; called by muse, mutect2, varscan2
- CPNE5 | c.*183A>G | 3'UTR (SNP) | VAF 40/248 reads (16%) | called by muse, mutect2, varscan2
- CRB1 | c.4005+1344C>T | Intron (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- CSPP1 | c.3077-612G>A | Intron (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- CTTNBP2NL | c.*1296A>G | 3'UTR (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2
- DCAF13 | c.624+1019G>A | Intron (SNP) | VAF 91/176 reads (52%) | catalogued as rs201666891; called by muse, mutect2, varscan2
- DPP10 | c.61-147399G>A | Intron (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- EFNB2 | c.*1210A>C | 3'UTR (SNP) | VAF 32/32 reads (100%) | called by muse, mutect2, varscan2
- ELF5 | c.385+407_385+410del | Intron (DEL) | VAF 48/129 reads (37%) | called by mutect2, pindel, varscan2
- GLRB | c.*1010G>C | 3'UTR (SNP) | VAF 16/29 reads (55%) | called by muse, mutect2, varscan2
- GTF3C3 | c.1390+335A>G | Intron (SNP) | VAF 65/110 reads (59%) | called by muse, mutect2, varscan2
- IGKV2-29 | n.113C>T | RNA (SNP) | VAF 99/204 reads (49%) | called by muse, mutect2, varscan2
- ITK | c.*2221C>T | 3'UTR (SNP) | VAF 42/109 reads (39%) | called by muse, mutect2, varscan2
- KBTBD6 | c.*2148A>G | 3'UTR (SNP) | VAF 56/60 reads (93%) | called by muse, mutect2, varscan2
- KLF12 | c.*510G>A | 3'UTR (SNP) | VAF 22/46 reads (48%) | called by muse, mutect2, varscan2
- LPP | c.*459C>T | 3'UTR (SNP) | VAF 26/103 reads (25%) | called by muse, mutect2, varscan2
- LRAT | c.*1827A>T | 3'UTR (SNP) | VAF 59/118 reads (50%) | called by muse, mutect2, varscan2
- LTB | c.163-32G>A | Intron (SNP) | VAF 288/625 reads (46%) | catalogued as rs773170624; called by muse, mutect2, varscan2
- MAF | c.*1028dup | 3'UTR (INS) | VAF 48/92 reads (52%) | catalogued as rs67402322; called by mutect2, varscan2
- MAP2K3 | c.50-2714A>C | Intron (SNP) | VAF 14/136 reads (10%) | called by muse, mutect2
- MBOAT2 | c.*3783C>A | 3'UTR (SNP) | VAF 60/121 reads (50%) | called by muse, mutect2, varscan2
- MBP | c.*529A>C | 3'UTR (SNP) | VAF 28/462 reads (6%) | called by muse, mutect2
- NAA20 | c.-32G>C | 5'UTR (SNP) | VAF 66/162 reads (41%) | catalogued as rs909220641; called by muse, mutect2, varscan2
- NEDD4 | c.*2697A>C | 3'UTR (SNP) | VAF 47/93 reads (51%) | called by muse, mutect2, varscan2
- NOP9 | c.*2237del | 3'UTR (DEL) | VAF 39/93 reads (42%) | called by mutect2, pindel, varscan2
- NUP160 | c.748+168T>A | Intron (SNP) | VAF 44/70 reads (63%) | called by muse, mutect2, varscan2
- PAX8 | c.602-53A>C | Intron (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
- PHB2 | c.789+13G>C | Intron (SNP) | VAF 18/19 reads (95%) | called by muse, mutect2, varscan2
- POLR3A | c.*1397dup | 3'UTR (INS) | VAF 26/67 reads (39%) | called by mutect2, pindel, varscan2
- PPM1L | c.*278G>A | 3'UTR (SNP) | VAF 62/108 reads (57%) | called by muse, mutect2, varscan2
- RALB | c.*666T>C | 3'UTR (SNP) | VAF 55/112 reads (49%) | called by muse, mutect2, varscan2
- SATB2 | c.*717C>T | 3'UTR (SNP) | VAF 15/80 reads (19%) | catalogued as rs929613421; called by muse, mutect2, varscan2
- SCN11A | c.*679G>C | 3'UTR (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- SEMA5A | c.*2579T>C | 3'UTR (SNP) | VAF 59/142 reads (42%) | called by muse, mutect2, varscan2
- SHOX2 | c.347-1005G>A | Intron (SNP) | VAF 56/118 reads (47%) | called by muse, mutect2, varscan2
- SLIT2 | c.1463-593C>T | Intron (SNP) | VAF 77/160 reads (48%) | called by muse, mutect2, varscan2
- STAMBP | c.*3887T>G | 3'UTR (SNP) | VAF 73/171 reads (43%) | called by muse, mutect2, varscan2
- STAT5A | c.2062+28C>T | Intron (SNP) | VAF 83/138 reads (60%) | called by muse, mutect2, varscan2
- SZT2 | c.10087-139A>T | Intron (SNP) | VAF 25/49 reads (51%) | called by muse, mutect2
- TEX35 | c.90+102G>A | Intron (SNP) | VAF 82/176 reads (47%) | called by muse, mutect2, varscan2
- TMOD3 | c.*2188_*2189insC | 3'UTR (INS) | VAF 22/49 reads (45%) | catalogued as rs1390699765; called by mutect2, varscan2
- TOX2 | c.*389_*393del | 3'UTR (DEL) | VAF 23/50 reads (46%) | called by mutect2, pindel, varscan2
- TP53 | c.-29+1111C>T | Intron (SNP) | VAF 17/32 reads (53%) | called by mutect2, varscan2
- TP53INP1 | c.*868C>T | 3'UTR (SNP) | VAF 39/100 reads (39%) | called by muse, mutect2, varscan2
- TTBK1 | c.*78C>G | 3'UTR (SNP) | VAF 20/36 reads (56%) | called by muse, mutect2, varscan2
- TWNK | c.*515C>T | 3'UTR (SNP) | VAF 13/110 reads (12%) | called by muse, mutect2, varscan2
- UBA1 | c.1939-47C>T | Intron (SNP) | VAF 36/95 reads (38%) | catalogued as COSV100255662; called by muse, mutect2, varscan2
- Unknown | chr2:111238429 C>T | IGR (SNP) | VAF 81/154 reads (53%) | called by muse, mutect2, varscan2
- WDR7 | c.*901C>T | 3'UTR (SNP) | VAF 50/111 reads (45%) | called by muse, mutect2, varscan2
- ZC3H14 | c.*3251C>T | 3'UTR (SNP) | VAF 32/93 reads (34%) | called by muse, mutect2, varscan2
- ZNF219 | c.-14T>C | 5'UTR (SNP) | VAF 54/277 reads (19%) | called by muse, mutect2, varscan2
